Somatic mutation profile of tumor specimen MMRF_1078_1_BM_CD138pos (aliquot MMRF_1078_1_BM_CD138pos_T2_TSE61_K02707) from MMRF case MMRF_1078, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.7 years (16,699 days).
Specimen MMRF_1078_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e193b1b-15a7-4f2e-8dd6-657c585c1b76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1078_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1078_1_PB_Whole_C1_TSE61_K02714; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ce08291-0643-4648-8589-bdca3b9f2c19

The open-access MAF lists 403 somatic variants for this specimen: 146 protein-altering or splice-affecting, 63 silent, 194 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 133, Missense Mutation 131, Silent 63, 5'UTR 23, 3'Flank 15, RNA 11, Nonsense Mutation 10, Intron 9, 5'Flank 3, Splice Region 2, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs780500242; called by muse, mutect2, varscan2
- ACTL6B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as rs748105438, COSV50514457, COSV50514641; called by muse, mutect2, varscan2
- ACTL7A | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs184507726; called by muse, mutect2
- ANO6 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV57661374; called by muse, mutect2, varscan2
- C6orf118 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV57814793; called by muse, mutect2, varscan2
- C9orf85 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV58253119; called by muse, mutect2, varscan2
- CCT8L2 | c.1646C>G p.T549R | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100742778; called by muse, mutect2, varscan2
- CD36 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs141475532; called by muse, mutect2, varscan2
- CDH18 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as rs541521243, COSV56900626; called by muse, mutect2, varscan2
- CPN2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); catalogued as rs1327499117; called by muse, mutect2
- CYP4F8 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs748139242, COSV100358192; called by muse, mutect2, varscan2
- DCBLD2 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs1459165500; called by muse, mutect2, varscan2
- DMD | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.682); catalogued as CM165381; called by muse, mutect2, varscan2
- DNM2 | c.2011A>G p.I671V (on ENST00000355667 / NM_001005360.3; = p.I667V on NM_004945.3) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as rs1568321953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELOA2 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV99797788; called by muse, mutect2
- EYS | c.4271C>T p.T1424M | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs762521982; called by muse, mutect2, varscan2
- F5 | c.4804G>C p.D1602H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1240931603; called by muse, mutect2
- F5 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV63129480; called by muse, mutect2, varscan2
- FANCB | c.1879C>T p.L627F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV60760840; called by muse, mutect2, varscan2
- FAT1 | c.4417A>C p.T1473P | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101499141; called by muse, mutect2, varscan2
- GAD1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60152075; called by muse, mutect2, varscan2
- GHRL | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99813893; called by muse, mutect2, varscan2
- HYPK | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV51039789; called by muse, mutect2, varscan2
- IL18R1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1223706178; called by muse, mutect2
- KCNH7 | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 10/155 reads (6%) | catalogued as rs1455357024, COSV59809990; called by muse, mutect2
- KIF13B | c.4546G>A p.V1516M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs1023818789; called by muse, mutect2, varscan2
- MACF1 | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 5/95 reads (5%) | catalogued as COSV58402059; called by muse, mutect2
- MUC16 | c.25741G>A p.E8581K | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); catalogued as COSV67449464, COSV67452321; called by muse, mutect2
- NBPF10 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100745056; called by mutect2, varscan2
- NLRP3 | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60231446; called by muse, mutect2
- OR2L8 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751730013; called by muse, mutect2, varscan2
- OR4K2 | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV53849377; called by muse, mutect2
- PLB1 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as rs1484236552; called by muse, mutect2, varscan2
- POT1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV62927755, COSV62930107, COSV62930155; called by muse, mutect2
- RASGRF1 | c.2689C>T p.R897C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775020496, COSV67249948; called by muse, mutect2, varscan2
- REM1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs1207791401; called by muse, mutect2
- RYR3 | c.11998C>G p.L4000V (on ENST00000389232; = p.L4001V on NM_001036.6) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211926; called by muse, mutect2, varscan2
- SLC26A3 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758633508, COSV60639959; called by muse, mutect2, varscan2
- SLC4A7 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55398789; called by muse, mutect2, varscan2
- STRN3 | c.748T>G p.F250V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100670608; called by muse, mutect2, varscan2
- TET2 | c.2375C>G p.S792* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV54419131; called by muse, mutect2, varscan2
- TGFB1 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs200868154, COSV54684009; called by muse, mutect2, varscan2
- TMEM63B | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs954585071; called by muse, mutect2, varscan2
- TRAF3 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61025109; called by muse, mutect2, varscan2
- TRIM32 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs754071735, COSV57758408; called by muse, mutect2, varscan2
- TRIP4 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV104380384; called by mutect2, varscan2
- TSHZ1 | c.2910C>G p.F970L (on ENST00000580243 / NM_001308210.2; = p.F925L on NM_005786.6) | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV59005106; called by muse, mutect2
- TTC30A | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs776398080, COSV53696374; called by muse, mutect2, varscan2
- TUBA3D | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100342482; called by muse, mutect2
- VIT | c.1460G>A p.S487N (on ENST00000389975 / NM_001177969.1; = p.S502N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1222093168; called by muse, mutect2, varscan2
- WSCD1 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100496370; called by mutect2, varscan2
- ZC3H6 | c.3092C>T p.S1031L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100674262, COSV59665750; called by muse, mutect2
- ZMYND8 | c.3371C>A p.S1124Y (on ENST00000311275 / NM_001363741.2; = p.S1098Y on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV53691386; called by muse, mutect2, varscan2
- ZNF780B | c.1315C>A p.H439N | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55464458; called by muse, mutect2
- AADACL2 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACAD10 | c.2405C>T p.S802L | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2
- ACTR1A | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- APPL2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- ARHGAP31 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ARL5B | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATG2B | c.3875C>T p.S1292F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- ATM | c.3158A>G p.D1053G | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALCOCO1 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPN6 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC54 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2
- CFAP53 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.341); called by muse, varscan2
- CFAP69 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | called by mutect2, varscan2
- CFHR5 | c.1076G>A p.C359Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC4G | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- COG2 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL11A1 | c.1648G>T p.G550W | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A1 | c.1351G>T p.G451C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPAMD8 | c.5645G>C p.R1882T (on ENST00000651564; = p.R1835T on NM_015692.5) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.192); called by muse, mutect2
- CYP4F12 | c.1398G>C p.R466S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4F8 | c.944A>T p.D315V | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CYTH1 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DDX52 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- DEFB115 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMC2 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM83G | c.1877C>G p.S626* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- FARP2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2
- FAT1 | c.2583T>G p.I861M | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- FAT1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FCGBP | c.10220C>G p.S3407C | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- FCHO2 | c.2311G>C p.V771L | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- FKTN | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSD1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- GALE | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.09); called by muse, mutect2
- GALNT9 | c.1368G>A p.M456I (on ENST00000328957 / NM_001122636.2; = p.M90I on NM_021808.3) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- GEN1 | c.168_170del p.L56del | In Frame Del (DEL) | VAF 20/42 reads (48%) | called by mutect2, pindel, varscan2
- GOLPH3L | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- GPAT2 | c.2031C>T p.L677= | Splice Region (SNP) | VAF 17/150 reads (11%) | called by muse, mutect2, varscan2
- HERC2 | c.9631G>A p.E3211K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMGXB3 | c.3760G>A p.E1254K (on ENST00000613459; = p.E1008K on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HOXB9 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HSPG2 | c.1495G>C p.V499L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGSF9 | c.3146G>A p.S1049N (on ENST00000368094 / NM_001135050.2; = p.S1033N on NM_020789.4) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2
- ITGA4 | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- KCNB1 | c.1962C>G p.I654M | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KCNK5 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- KIF21A | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LINS1 | c.1715C>G p.T572R | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LOXHD1 | c.2907G>C p.E969D | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.373); called by muse, mutect2
- LRP4 | c.1160C>G p.T387R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPHOSPH9 | c.3095G>A p.R1032K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.045); called by muse, mutect2
- NHS | c.2454C>A p.S818R | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- NOP10 | c.194G>C p.*65Sext*58 | Nonstop Mutation (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- NUBP1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- NUTM2F | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2
- OR2G2 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- OR5L2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.151); called by muse, mutect2
- PALLD | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDCL3 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PDE3A | c.1828C>G p.R610G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGM3 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PLXNA1 | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PRUNE2 | c.7252G>C p.E2418Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- QSOX1 | c.1655G>T p.R552L | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2
- RAPH1 | c.793G>A p.E265K (on ENST00000319170 / NM_213589.3; = p.E317K on NM_203365.4) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RBM6 | c.1857G>C p.K619N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2
- RBMS2 | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- RFX7 | c.2983G>A p.D995N (on ENST00000559447 / NM_001368074.1; = p.D1092N on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- S100A11 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- SEC23A | c.705A>C p.K235N | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEMA6A | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- SH3D19 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- SLTM | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2
- SOX2 | c.12G>C p.M4I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.095); called by muse, mutect2
- SRPRA | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by mutect2, varscan2
- ST7 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUCO | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SULF1 | c.2427G>A p.Q809= | Splice Region (SNP) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- TAS2R3 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, mutect2
- TIAM2 | c.4625G>A p.G1542E (on ENST00000529824; = p.G1513E on NM_012454.3) | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.167); called by muse, mutect2
- TMCC1 | c.1264G>T p.D422Y (on ENST00000393238 / NM_001349268.2; = p.D98Y on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAF3 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- TRAF3 | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIP4 | c.1713G>C p.K571N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- TUBE1 | c.60C>G p.F20L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, varscan2
- UBASH3A | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- UBE3C | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- UBR1 | c.2118G>T p.K706N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- UQCRC1 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- VSNL1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- ZBTB46 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF274 | c.1237G>C p.D413H (on ENST00000610905; = p.D308H on NM_016324.3) | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- APOA1 | c.18G>A p.L6= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- CACNA1C | c.6291G>A p.G2097= (on ENST00000399634 / NM_001167625.1; = p.G2026= on NM_000719.7) | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- CDHR1 | c.2307C>G p.L769= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- CFAP65 | c.2505G>A p.Q835= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- CHST1 | c.819C>T p.T273= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- CLMP | c.93C>T p.V31= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV101507464; called by muse, mutect2
- CRYBG2 | c.3183C>A p.G1061= | Silent (SNP) | VAF 47/88 reads (53%) | called by muse, mutect2, varscan2
- CTDSP1 | c.595C>T p.L199= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as rs761822791; called by muse, mutect2, varscan2
- ENOX2 | c.1827G>T p.L609= (on ENST00000338144 / NM_001382520.1; = p.L580= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, varscan2
- GLI2 | c.2016G>A p.G672= (on ENST00000361492 / NM_001374353.1; = p.G689= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV58051238, COSV58052541; called by muse, mutect2
- GOLGA4 | c.6006T>C p.N2002= | Silent (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- GRIA2 | c.739C>T p.L247= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV52411854; called by muse, mutect2
- GRIN2C | c.1707C>T p.I569= | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- GRK7 | c.828C>G p.L276= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- H3C4 | c.168G>A p.Q56= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1263235235, COSV61912132; called by muse, mutect2
- HNF1A | c.543G>A p.G181= | Silent (SNP) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- ICE1 | c.5760G>A p.K1920= | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- ILVBL | c.1137G>A p.E379= | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- INO80D | c.2802C>T p.F934= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as rs374893679; called by muse, mutect2, varscan2
- ITFG1 | c.99G>A p.A33= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV54522364; called by muse, mutect2, varscan2
- KRT71 | c.1023C>T p.L341= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- KRTAP12-3 | c.189C>T p.I63= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as rs202040706; called by muse, mutect2, varscan2
- MLIP | c.312G>C p.T104= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV51433839, COSV99230786; called by muse, mutect2
- MRGPRX1 | c.534C>T p.F178= | Silent (SNP) | VAF 13/300 reads (4%) | catalogued as COSV100245937; called by muse, mutect2
- NELFCD | c.1503G>A p.L501= (on ENST00000602795; = p.L483= on NM_198976.4) | Silent (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- NOM1 | c.36G>A p.P12= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2
- NTHL1 | c.318G>A p.K106= (on ENST00000219066; = p.K98= on NM_002528.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- OR2T34 | c.594C>T p.S198= | Silent (SNP) | VAF 66/538 reads (12%) | catalogued as rs1392381767, COSV60902142, COSV60902177; called by muse, mutect2, varscan2
- OR5M3 | c.546C>T p.L182= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV56566031; called by muse, mutect2
- OR8B12 | c.828C>T p.F276= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- PAX3 | c.516G>A p.L172= | Silent (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1380C>T p.T460= | Silent (SNP) | VAF 88/319 reads (28%) | catalogued as rs142802947, COSV65351500; called by muse, mutect2, varscan2
- PDK3 | c.199C>T p.L67= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- PITPNM2 | c.2869C>T p.L957= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.1392C>A p.L464= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV52216618; called by muse, mutect2, varscan2
- PNPLA4 | c.117C>T p.F39= | Silent (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- POC1A | c.171C>T p.F57= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- PRAMEF2 | c.861G>A p.L287= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as rs1424113592; called by muse, mutect2
- PRDM11 | c.1203C>G p.V401= (on ENST00000530656 / NM_001359633.1; = p.V367= on NM_001256695.1) | Silent (SNP) | VAF 34/204 reads (17%) | called by muse, mutect2, varscan2
- RYR1 | c.8107C>T p.L2703= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- SCN10A | c.3108C>G p.V1036= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- SCN8A | c.4851A>T p.R1617= | Silent (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2, varscan2
- SEZ6L | c.1446G>A p.T482= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs142670064, COSV50657759; called by muse, mutect2, varscan2
- SLC37A3 | c.138C>T p.V46= | Silent (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- SLC4A9 | c.2301C>T p.L767= (on ENST00000507527 / NM_001258428.2; = p.L743= on NM_031467.3) | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- SMPD4 | c.1551G>T p.L517= (on ENST00000409031 / NM_017951.4; = p.L488= on NM_017751.4) | Silent (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- SPATA1 | c.1308C>T p.L436= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99759624; called by muse, mutect2, varscan2
- TAS2R4 | c.708C>T p.L236= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs1261337026, COSV99924660; called by muse, mutect2, varscan2
- TMC6 | c.681G>A p.L227= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- TMCC1 | c.1167G>C p.L389= (on ENST00000393238 / NM_001349268.2; = p.L65= on NM_015008.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 10/133 reads (8%) | called by muse, mutect2
- TMCO1 | c.183C>T p.L61= (on ENST00000612311 / NM_001256164.1; = p.L10= on NM_019026.6) | Silent (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- TRPM8 | c.1422C>A p.V474= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1314405166; called by muse, mutect2, varscan2
- TTN | c.100323G>T p.V33441= (on ENST00000591111; = p.V26017= on NM_003319.4) | Silent (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2, varscan2
- TYK2 | c.213C>T p.F71= | Silent (SNP) | VAF 23/206 reads (11%) | called by muse, mutect2, varscan2
- UACA | c.2913G>A p.K971= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV59853227; called by muse, mutect2
- VPS39 | c.1597C>T p.L533= (on ENST00000348544 / NM_001301138.2; = p.L522= on NM_015289.5) | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV58787529; called by muse, mutect2
- XYLB | c.1605G>A p.P535= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs537197841, COSV52915539; called by muse, mutect2, varscan2
- ZFP37 | c.72G>C p.T24= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV65287079; called by muse, mutect2
- ZMYND15 | c.1164C>T p.F388= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV52645218; called by muse, mutect2
- ZNF239 | c.165C>T p.F55= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs778354079, COSV60018248; called by muse, mutect2, varscan2
- ZNF347 | c.1515C>T p.V505= | Silent (SNP) | VAF 23/342 reads (7%) | called by muse, mutect2
- ZNF608 | c.3351G>A p.Q1117= | Silent (SNP) | VAF 28/145 reads (19%) | called by muse, mutect2, varscan2
- ZNF622 | c.999C>T p.L333= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- AAK1 | c.*4549C>G | 3'UTR (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- ABLIM1 | chr10:114435410 A>C | 3'Flank (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- AC004593.2 | c.*740G>A | 3'UTR (SNP) | VAF 16/247 reads (6%) | called by muse, mutect2
- ACAP2 | c.*367C>A | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- ADAM29 | c.-602G>A | 5'UTR (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- ADAM6 | n.1459C>T | RNA (SNP) | VAF 162/165 reads (98%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.*1390C>A | 3'UTR (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- ADCY1 | c.*817G>A | 3'UTR (SNP) | VAF 72/142 reads (51%) | called by muse, mutect2, varscan2
- ADGRL2 | c.*93G>C | 3'UTR (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- AGRN | c.*754G>C | 3'UTR (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- ALX1 | c.*297T>C | 3'UTR (SNP) | VAF 15/18 reads (83%) | called by muse, mutect2, varscan2
- AMOTL1 | c.*428G>C | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- AP2A2 | c.*1337C>T | 3'UTR (SNP) | VAF 14/201 reads (7%) | called by muse, mutect2
- ARFGEF1 | c.*206G>C | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- ARL6IP6 | c.*595G>A | 3'UTR (SNP) | VAF 47/96 reads (49%) | catalogued as COSV58443441; called by muse, mutect2, varscan2
- ATP8B2 | c.*1698C>T | 3'UTR (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- BASP1-AS1 | n.1256C>T | RNA (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- BDH2 | c.*1226G>A | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- BMF | c.*3375G>T | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- BNC2 | c.*7152C>T | 3'UTR (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- BNC2 | c.*3265C>T | 3'UTR (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- BPNT2 | c.*5473G>C | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- C1orf109 | c.*844C>T | 3'UTR (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- CACNA1C | chr12:2696269 G>A | 3'Flank (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- CAMKK1 | c.*744G>A | 3'UTR (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- CASP9 | c.*334C>T | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- CD36 | c.-328G>C | 5'UTR (SNP) | VAF 5/126 reads (4%) | called by muse, mutect2
- CDK10 | c.*506G>A | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- CENPF | c.-54C>T | 5'UTR (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- CFAP47 | c.*75G>A | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- CHMP7 | c.-61G>C | 5'UTR (SNP) | VAF 12/85 reads (14%) | catalogued as rs1399289988, COSV100500792; called by muse, mutect2, varscan2
- CLPB | c.*780G>C | 3'UTR (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- CNGA1 | c.*113G>A | 3'UTR (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.*990G>A | 3'UTR (SNP) | VAF 26/694 reads (4%) | called by muse, mutect2
- COA7 | c.*662G>A | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- COL14A1 | c.*138del | 3'UTR (DEL) | VAF 8/34 reads (24%) | catalogued as COSV99918729; called by mutect2, pindel, varscan2
- COL6A4P1 | n.2176C>T | RNA (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- COLCA2 | chr11:111294269 T>C | 5'Flank (SNP) | VAF 10/15 reads (67%) | catalogued as rs562187507; called by muse, mutect2, varscan2
- CORO2B | c.*1439C>T | 3'UTR (SNP) | VAF 15/129 reads (12%) | catalogued as rs1032457294; called by muse, mutect2, varscan2
- CSDE1 | c.*627G>T | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- CTBP2 | c.*2829G>C | 3'UTR (SNP) | VAF 12/106 reads (11%) | catalogued as rs1321741397; called by muse, mutect2, varscan2
- CTDSPL | c.*1446G>A | 3'UTR (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2
- CYP26B1 | c.*1622G>T | 3'UTR (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- DENR | c.*1498C>T | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- DLX6-AS1 | n.489G>C | RNA (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- DOLK | c.-56G>A | 5'UTR (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- DYSF | c.*237C>G | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- EDEM3 | c.*1986G>A | 3'UTR (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- EDIL3 | c.*941G>T | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- ELN | c.377-9C>G | Intron (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- ELP4 | chr11:31787490 G>T | 3'Flank (SNP) | VAF 68/120 reads (57%) | called by muse, mutect2, varscan2
- EPN2 | c.*657C>G | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- ETV3L | c.*451C>G | 3'UTR (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- FEM1C | c.*1989C>G | 3'UTR (SNP) | VAF 11/62 reads (18%) | catalogued as rs1475992942; called by muse, mutect2, varscan2
- FLT3 | c.*482C>G | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- FOXK2 | c.*1066C>T | 3'UTR (SNP) | VAF 8/75 reads (11%) | catalogued as rs1268976251; called by muse, mutect2, varscan2
- FOXO3 | c.*702G>A | 3'UTR (SNP) | VAF 36/276 reads (13%) | called by muse, mutect2, varscan2
- GABARAPL1 | c.*1141C>T | 3'UTR (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- GABRG2 | c.*526C>T | 3'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- GALNT13 | c.*868G>A | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- GATAD1 | c.-212G>A | 5'UTR (SNP) | VAF 7/14 reads (50%) | catalogued as rs1191567057; called by muse, mutect2, varscan2
- GDA | c.*1000C>T | 3'UTR (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- GIMAP7 | c.-66G>A | 5'UTR (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- GNB4 | c.*4949G>A | 3'UTR (SNP) | VAF 8/185 reads (4%) | called by muse, mutect2
- GPD2 | c.*853G>A | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- GPR85 | c.*2182G>C | 3'UTR (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- GRAMD2A | c.*1279C>T | 3'UTR (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- GRID1 | c.*1687C>T | 3'UTR (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2, varscan2
- H3-3B | c.*1464G>C | 3'UTR (SNP) | VAF 14/134 reads (10%) | called by muse, varscan2
- H3-3B | c.*948G>A | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- HDGFL3 | c.*315C>T | 3'UTR (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- HDHD3 | c.-232G>C | 5'UTR (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75565299 A>C | 3'Flank (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- HSPA4 | c.-165C>G | 5'UTR (SNP) | VAF 6/74 reads (8%) | catalogued as rs981473090, COSV100507663; called by muse, mutect2
- IER3IP1 | c.*471G>C | 3'UTR (SNP) | VAF 5/43 reads (12%) | catalogued as rs1356622538; called by muse, mutect2, varscan2
- IFNAR2 | c.-181G>A | 5'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- INSM1 | c.*652C>T | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- IRS2 | c.*2359G>A | 3'UTR (SNP) | VAF 9/24 reads (38%) | catalogued as rs781092607; called by muse, mutect2, varscan2
- JAKMIP2 | c.*412C>T | 3'UTR (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- KCNA7 | c.*1775G>T | 3'UTR (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- KCNC1 | c.*1757G>C | 3'UTR (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- KCNMA1 | c.*5586C>T | 3'UTR (SNP) | VAF 10/68 reads (15%) | catalogued as rs759876041; called by muse, mutect2, varscan2
- KLHL24 | c.*4156A>G | 3'UTR (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- KREMEN1 | chr22:29144734 C>T | 3'Flank (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- KREMEN1 | chr22:29145299 C>G | 3'Flank (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- LANCL1 | chr2:210431609 C>T | 3'Flank (SNP) | VAF 6/133 reads (5%) | called by muse, mutect2
- LARP1 | c.*2229C>T | 3'UTR (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- LETM1 | c.*1827C>G | 3'UTR (SNP) | VAF 11/102 reads (11%) | catalogued as rs1289431635; called by muse, mutect2, varscan2
- LINC00930 | n.3185C>T | RNA (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- LIPT1 | c.-93C>G | 5'UTR (SNP) | VAF 13/61 reads (21%) | catalogued as rs776826901; called by muse, mutect2, varscan2
- LVRN | c.*165G>A | 3'UTR (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- MAGI2 | c.1103+10577G>T | Intron (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- MED30 | c.*164T>A | 3'UTR (SNP) | VAF 4/51 reads (8%) | catalogued as COSV52066507; called by muse, mutect2
- MEI1 | chr22:41694639 G>T | 5'Flank (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- MEIS2 | c.*751C>T | 3'UTR (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- MOBP | chr3:39525834 C>G | 3'Flank (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- MPZ | c.*74_*95delinsC | 3'UTR (DEL) | VAF 8/32 reads (25%) | called by pindel, varscan2*
- MRPL34 | c.*39C>T | 3'UTR (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- MRPL34 | c.*324C>G | 3'UTR (SNP) | VAF 3/42 reads (7%) | catalogued as rs1332423290; called by muse, mutect2
- MSN | c.*1156C>T | 3'UTR (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- MTSS2 | c.*2438G>A | 3'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as rs981780979; called by mutect2, varscan2
- MTTP | c.*299G>T | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- MYO1B | c.*671G>A | 3'UTR (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- NAA15 | c.*2489G>A | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- NCMAP | c.*1197G>A | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- NEURL1B | c.*2747G>C | 3'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as rs1244728297; called by muse, mutect2, varscan2
- NKAIN3 | c.533-10293G>A | Intron (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- NSD1 | c.*1928G>C | 3'UTR (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- NXF4 | n.3330C>T | RNA (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- OR7E5P | n.233A>G | RNA (SNP) | VAF 202/349 reads (58%) | called by muse, mutect2, varscan2
- PACS2 | chr14:105396720 C>G | 3'Flank (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- PARP16 | c.*1189C>A | 3'UTR (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- PARP3 | c.-415G>A | 5'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67231C>T | Intron (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- PDS5B | c.*1837C>A | 3'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- PIGT | c.*398A>G | 3'UTR (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- PLAGL2 | c.*1294C>G | 3'UTR (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
- PLEKHG3 | chr14:64747238 G>C | 3'Flank (SNP) | VAF 6/43 reads (14%) | called by mutect2, varscan2
- PMCHL2 | n.1544C>A | RNA (SNP) | VAF 26/55 reads (47%) | called by muse, varscan2
- PNKD | c.*1126C>G | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- POU2AF1 | c.*114C>T | 3'UTR (SNP) | VAF 9/111 reads (8%) | catalogued as rs539159649; called by muse, mutect2
- PPP1R3F | c.*122C>G | 3'UTR (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- PPP2R1B | c.*1048G>C | 3'UTR (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- PPP3R1 | c.*1002G>A | 3'UTR (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- PRDM1 | c.-196G>A | 5'UTR (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- PRKCB | c.1864-2598G>C | Intron (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2
- PROCR | c.*34G>C | 3'UTR (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99405773; called by muse, mutect2, varscan2
- PRR14L | c.*1922G>A | 3'UTR (SNP) | VAF 44/69 reads (64%) | called by muse, mutect2, varscan2
- PRR15L | c.*403C>G | 3'UTR (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- PRR34-AS1 | n.751C>A | RNA (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- PTPRB | chr12:70518887 G>A | 3'Flank (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- RAB38 | c.*598G>C | 3'UTR (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- RDH10 | c.*1857G>A | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- RDH10 | c.*1982G>A | 3'UTR (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- RPS6KB1 | c.*3229C>G | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- SCAMP5 | c.*1673G>A | 3'UTR (SNP) | VAF 10/116 reads (9%) | catalogued as rs1008694053; called by muse, mutect2
- SCN1A | c.*1505C>T | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- SELENOI | c.*4492G>C | 3'UTR (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- SEPTIN5 | c.*424G>A | 3'UTR (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- SEPTIN8 | c.1286+3930G>A | Intron (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- SGK1 | c.-13C>T | 5'UTR (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- SGMS1 | c.-607G>A | 5'UTR (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- SHISA4 | c.*176G>A | 3'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- SLC14A2 | c.*182C>G | 3'UTR (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- SLC17A8 | c.*1471A>G | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- SLC25A20 | c.*599T>A | 3'UTR (SNP) | VAF 77/98 reads (79%) | called by muse, mutect2, varscan2
- SLC25A23 | c.*727C>G | 3'UTR (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- SLC6A14 | c.*475G>C | 3'UTR (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- SLC7A11 | c.-206G>A | 5'UTR (SNP) | VAF 12/60 reads (20%) | catalogued as rs1169179729; called by muse, varscan2
- SLC8A2 | c.*691G>C | 3'UTR (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- SLITRK6 | c.*415G>A | 3'UTR (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- SMAD3 | c.533-590C>T | Intron (SNP) | VAF 52/109 reads (48%) | catalogued as rs1032790641; called by muse, mutect2, varscan2
- SMCP | c.-102G>A | 5'UTR (SNP) | VAF 10/63 reads (16%) | catalogued as COSV64217810; called by muse, mutect2, varscan2
- SMU1 | c.*2379C>T | 3'UTR (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- SNORA22 | chr7:65759238 G>A | 3'Flank (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- SNTB2 | c.*6903A>T | 3'UTR (SNP) | VAF 19/31 reads (61%) | called by muse, varscan2
- SPATA13 | c.-222-25350G>A | Intron (SNP) | VAF 9/32 reads (28%) | catalogued as rs1566159781; called by muse, mutect2, varscan2
- STEAP3 | c.*1330G>A | 3'UTR (SNP) | VAF 11/104 reads (11%) | catalogued as rs1296097944; called by muse, mutect2, varscan2
- STK17A | c.*1098G>C | 3'UTR (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- SYN3 | c.*918G>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- SYNGAP1 | c.*1312C>T | 3'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- SYNPO | chr5:150657040 C>T | 3'Flank (SNP) | VAF 4/29 reads (14%) | catalogued as rs530746865, COSV51739771, COSV99770883; called by muse, mutect2
- TAF1B | c.*42G>A | 3'UTR (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- TAL1 | c.-430G>A | 5'UTR (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- THAP6 | c.*2218G>C | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- THEG | c.*13C>A | 3'UTR (SNP) | VAF 17/113 reads (15%) | catalogued as COSV100700626; called by muse, mutect2, varscan2
- TMEM132B | c.*280G>A | 3'UTR (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- TMEM267 | c.*1435G>A | 3'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, varscan2
- TNNI1 | chr1:201407955 A>C | 3'Flank (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- TNRC6B | c.*5231C>G | 3'UTR (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- TP53BP2 | c.*491_*492insAATA | 3'UTR (INS) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- TRIM13 | c.*4229G>C | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- TRIM8 | c.*1396C>T | 3'UTR (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- TSC22D2 | c.-195G>C | 5'UTR (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- TTC41P | n.1165G>A | RNA (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- TXNDC5 | c.*1128G>A | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- UBE3D | c.-42C>G | 5'UTR (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- UBN2 | c.*9086G>A | 3'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- USP9X | c.-446G>A | 5'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- VANGL1 | chr1:115691969 G>C | 3'Flank (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- VAPA | c.*4818C>T | 3'UTR (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- VMP1 | c.*1372G>A | 3'UTR (SNP) | VAF 12/94 reads (13%) | catalogued as rs779350466; called by muse, mutect2
- VPS52 | c.*137C>T | 3'UTR (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- VPS53 | c.*3862G>A | 3'UTR (SNP) | VAF 5/23 reads (22%) | catalogued as rs1355452750; called by muse, mutect2, varscan2
- WBP11P1 | n.2137G>A | RNA (SNP) | VAF 22/192 reads (11%) | called by muse, mutect2, varscan2
- YIPF5 | chr5:144170988 C>T | 5'Flank (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- ZDHHC6 | c.-396G>A | 5'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- ZNF264 | c.-361C>T | 5'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- ZNF3 | c.*324C>T | 3'UTR (SNP) | VAF 14/193 reads (7%) | catalogued as rs1044181562; called by muse, mutect2
- ZNF43 | c.*7C>T | 3'UTR (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- ZNF776 | c.*122C>T | 3'UTR (SNP) | VAF 7/150 reads (5%) | catalogued as rs980299061; called by muse, mutect2
- ZNF880 | c.*112C>G | 3'UTR (SNP) | VAF 14/271 reads (5%) | catalogued as COSV101424986; called by muse, mutect2
- ZNF91 | c.*285C>T | 3'UTR (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- ZSCAN18 | c.49+10462C>T | Intron (SNP) | VAF 16/269 reads (6%) | called by muse, mutect2
